Gene-level copy-number profile of tumor specimen C3L-02617-03 from CPTAC case C3L-02617, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.9 years (23,710 days).
Specimen C3L-02617-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0d354cc7-3bd5-4eb1-8d7d-c897b8fa734e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02617-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/a00a6c17-6002-4a56-8b88-5096514d3125

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 24,660; copy number 2: 31,197; copy number 3: 2,027; copy number 4: 215; copy number 5: 170; copy number 6: 104; copy number 11: 4.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,875,171–143,905,966, 2 genes (within-gene range 0–1): H2BP2, H3-2.
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.
- chr9:13,927,971–14,069,417, 5 genes: LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr14:55,366,391–55,796,731, 12 genes: ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 278 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,154,761–42,155,820, 149 genes, copy number 5–6 (broad region; genes not listed).
- chr3:181,847,526–182,035,644, 4 genes, copy number 11: AC007547.2, AC007547.1, LINC01206, RN7SKP265.
- chr4:51,843,000–57,207,459, 116 genes, copy number 5 (broad region; genes not listed).
- chr11:57,376,769–57,515,780, 9 genes, copy number 6: PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1, SLC43A1.

Autosomal genes at a single copy (total copy number 1): 24,660. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
